Somatic mutation profile of tumor specimen MMRF_1913_2_BM_CD138pos (aliquot MMRF_1913_2_BM_CD138pos_T1_KHS5U_L14862) from MMRF case MMRF_1913, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 79.6 years (29,059 days).
Specimen MMRF_1913_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2a8b6de8-0337-43ce-a7ed-4650ccb3fd66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1913_2_PB_WBC (Blood Derived Normal), aliquot MMRF_1913_2_PB_WBC_C2_KHS5U_L14863; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/17c4489f-d756-4d86-b749-73726fd14c27

The open-access MAF lists 175 somatic variants for this specimen: 72 protein-altering or splice-affecting, 21 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, 3'UTR 39, Intron 21, Silent 21, 5'UTR 11, 3'Flank 5, RNA 4, 5'Flank 2, Nonsense Mutation 2, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRL2 | c.2786G>T p.C929F (on ENST00000370717 / NM_001366005.1; = p.C916F on NM_012302.4) | Missense Mutation (SNP) | VAF 87/224 reads (39%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.954); catalogued as rs947047129; called by muse, mutect2, varscan2
- CHP2 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs149498782, COSV100270182; called by muse, varscan2
- CPN2 | c.1185C>A p.N395K | Missense Mutation (SNP) | VAF 56/140 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781735657; called by muse, mutect2, varscan2
- CRISPLD1 | c.352C>A p.Q118K | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV51551097; called by muse, mutect2
- DCLK2 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 130/341 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs980372267; called by muse, mutect2, varscan2
- EPPK1 | c.6458C>T p.T2153M | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.349); catalogued as rs201994568, COSV73262096; called by muse, mutect2, varscan2
- GAB1 | c.509A>G p.H170R | Missense Mutation (SNP) | VAF 87/206 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs577943139; called by muse, mutect2, varscan2
- GGA2 | c.8C>T p.A3V | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.939); catalogued as rs1210270741; called by muse, mutect2, varscan2
- IGHV1-69 | c.244A>C p.K82Q | Missense Mutation (SNP) | VAF 84/265 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs781895266; called by muse, mutect2
- IGHV2-70 | c.125C>G p.T42S | Missense Mutation (SNP) | VAF 30/42 reads (71%) | SIFT tolerated (0.53); PolyPhen benign (0.061); catalogued as rs369724963; called by muse, varscan2
- IGLL5 | c.107A>T p.H36L | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as rs544159503, COSV73251092; called by muse, mutect2, varscan2
- IGLV3-1 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 88/161 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as rs142180628; called by muse, varscan2
- IRS2 | c.3436C>A p.R1146S | Missense Mutation (SNP) | VAF 69/167 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV65480108; called by muse, mutect2, varscan2
- KRTAP10-10 | c.111C>A p.S37R | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV100552954; called by muse, mutect2, varscan2
- PCDHA7 | c.2041C>T p.R681W | Missense Mutation (SNP) | VAF 83/175 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as rs782375452, COSV65338628; called by muse, mutect2, varscan2
- PDCD7 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1425365085; called by muse, mutect2
- PGS1 | c.1348G>T p.E450* | Nonsense Mutation (SNP) | VAF 14/272 reads (5%) | catalogued as rs1258616988; called by muse, mutect2
- PPP4R3A | c.818T>C p.M273T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs1352814952; called by muse, mutect2, varscan2
- PRSS38 | c.29C>A p.P10Q | Missense Mutation (SNP) | VAF 17/130 reads (13%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as COSV100816485; called by muse, mutect2, varscan2
- TENM1 | c.2764G>A p.D922N | Missense Mutation (SNP) | VAF 28/37 reads (76%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.591); catalogued as COSV64434878; called by muse, mutect2, varscan2
- TMEM45A | c.227A>G p.H76R | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV100058346; called by muse, mutect2, varscan2
- TMTC1 | c.2092C>T p.R698* (on ENST00000539277 / NM_001193451.2; = p.R590* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 37/115 reads (32%) | catalogued as rs1217822717, COSV55491829, COSV99760541; called by muse, mutect2, varscan2
- VSIG2 | c.579G>A p.M193I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs530449056; called by muse, mutect2, varscan2
- AATF | c.1177T>G p.L393V | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- ATP5MC1 | c.211G>A p.G71S | Missense Mutation (SNP) | VAF 58/151 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.314); called by muse, mutect2, varscan2
- BEST2 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- C2orf78 | c.1924A>G p.K642E | Missense Mutation (SNP) | VAF 64/187 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- CACNA2D3 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 113/274 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CALHM6 | c.885T>A p.D295E | Missense Mutation (SNP) | VAF 115/199 reads (58%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- CCAR1 | c.893dup p.S299Ifs*8 | Frame Shift Ins (INS) | VAF 75/266 reads (28%) | called by mutect2, pindel, varscan2
- CDH11 | c.100T>C p.S34P | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHODL | c.575A>C p.K192T | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CNTN5 | c.836G>T p.R279I | Missense Mutation (SNP) | VAF 13/227 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- COL12A1 | c.2281G>T p.A761S | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2
- COL4A4 | c.323A>C p.D108A | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- CPEB4 | c.1780+1G>A p.X594_splice | Splice Site (SNP) | VAF 96/236 reads (41%) | called by muse, mutect2, varscan2
- CYRIB | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- DIS3 | c.1433T>A p.V478E | Missense Mutation (SNP) | VAF 94/138 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DPH3 | c.88G>A p.D30N | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- EDEM1 | c.1391C>G p.A464G | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.289); called by muse, varscan2
- EFCAB5 | c.4003C>A p.L1335I | Missense Mutation (SNP) | VAF 137/359 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.668); called by muse, mutect2, varscan2
- FAM149A | c.979A>G p.I327V (on ENST00000356371 / NM_001367768.2; = p.I36V on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- HNRNPA3 | c.182T>C p.L61P | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGLV4-69 | c.196T>G p.Y66D | Missense Mutation (SNP) | VAF 77/183 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- IRX2 | c.655G>T p.G219W | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- KIF27 | c.1822C>T p.P608S | Missense Mutation (SNP) | VAF 118/362 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, varscan2
- LAMA1 | c.6237C>A p.N2079K | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- LRP1B | c.1790A>C p.D597A | Missense Mutation (SNP) | VAF 46/99 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- LRRN3 | c.445C>T p.H149Y | Missense Mutation (SNP) | VAF 19/246 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAGEL2 | c.2306T>A p.L769Q | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.09); called by muse, mutect2
- MOCOS | c.1687A>G p.T563A | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.28255G>A p.V9419M | Missense Mutation (SNP) | VAF 95/250 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- NOX5 | c.2066G>T p.G689V | Missense Mutation (SNP) | VAF 60/212 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR11H4 | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 28/400 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- OTOL1 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAX3 | c.670A>G p.T224A | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PHF12 | c.1930A>C p.K644Q | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- PNPLA5 | c.384C>A p.N128K | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PODXL | c.530A>T p.H177L | Missense Mutation (SNP) | VAF 153/262 reads (58%) | SIFT tolerated (0.12); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PPRC1 | c.1262A>T p.K421M | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- PRSS38 | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTDSS1 | c.70A>C p.I24L | Missense Mutation (SNP) | VAF 73/221 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ROR1 | c.1663A>T p.I555F | Missense Mutation (SNP) | VAF 51/137 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SBSN | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 87/225 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.037); called by muse, varscan2
- SMAP1 | c.262G>A p.D88N | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- STK33 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.308); called by muse, mutect2
- STYXL2 | c.2144G>A p.G715E | Missense Mutation (SNP) | VAF 52/245 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- TMEM145 | c.472T>A p.F158I | Missense Mutation (SNP) | VAF 85/258 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- TSC22D2 | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 105/277 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTN | c.42118C>A p.P14040T (on ENST00000591111; = p.P6616T on NM_003319.4) | Missense Mutation (SNP) | VAF 122/313 reads (39%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZC2HC1A | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 85/227 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ZFHX3 | c.1358C>T p.S453F | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- AC139530.2 | c.45G>T p.G15= | Silent (SNP) | VAF 17/41 reads (41%) | called by muse, mutect2, varscan2
- AEBP1 | c.573C>T p.P191= | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as rs376847554; called by muse, mutect2, varscan2
- B3GALT4 | c.342G>A p.P114= | Silent (SNP) | VAF 60/260 reads (23%) | catalogued as COSV65851858; called by muse, mutect2, varscan2
- CAPN2 | c.777G>A p.V259= | Silent (SNP) | VAF 33/207 reads (16%) | called by muse, mutect2, varscan2
- CCER1 | c.444C>T p.R148= | Silent (SNP) | VAF 45/127 reads (35%) | catalogued as COSV62646982; called by muse, mutect2, varscan2
- CEP350 | c.8247A>G p.E2749= | Silent (SNP) | VAF 51/234 reads (22%) | catalogued as COSV62603950; called by muse, mutect2, varscan2
- CHRNB3 | c.468C>T p.D156= | Silent (SNP) | VAF 139/325 reads (43%) | catalogued as rs779906426, COSV51494874, COSV51495474; called by muse, mutect2, varscan2
- DDX60 | c.3361C>T p.L1121= | Silent (SNP) | VAF 29/74 reads (39%) | called by muse, mutect2, varscan2
- H2BC4 | c.147C>T p.V49= | Silent (SNP) | VAF 116/400 reads (29%) | catalogued as rs1409067459, COSV58417871; called by muse, mutect2, varscan2
- IGHV2-70 | c.126C>T p.T42= | Silent (SNP) | VAF 28/40 reads (70%) | catalogued as rs548315389; called by muse, varscan2
- MYPOP | c.930G>A p.L310= | Silent (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- NAT8 | c.660T>C p.P220= | Silent (SNP) | VAF 63/179 reads (35%) | called by muse, mutect2, varscan2
- NEB | c.11721G>A p.T3907= | Silent (SNP) | VAF 28/124 reads (23%) | catalogued as rs531949723; called by muse, mutect2, varscan2
- NSG2 | c.477C>T p.V159= | Silent (SNP) | VAF 64/158 reads (41%) | catalogued as rs747207528, COSV57458412; called by muse, mutect2, varscan2
- OR4K17 | c.672C>A p.T224= | Silent (SNP) | VAF 77/183 reads (42%) | catalogued as rs1372885381, COSV59647669; called by muse, mutect2, varscan2
- PIGP | c.273A>G p.V91= (on ENST00000464265 / NM_153681.2; = p.V41= on NM_016430.4) | Silent (SNP) | VAF 87/242 reads (36%) | called by muse, mutect2, varscan2
- PLET1 | c.306C>T p.Y102= | Silent (SNP) | VAF 42/105 reads (40%) | catalogued as rs1027433361; called by muse, mutect2, varscan2
- PXDN | c.807C>T p.A269= | Silent (SNP) | VAF 44/131 reads (34%) | catalogued as rs562231688; called by muse, mutect2, varscan2
- RNF213 | c.5091G>A p.E1697= | Silent (SNP) | VAF 16/257 reads (6%) | catalogued as rs1430764498; called by muse, mutect2
- SALL3 | c.612G>T p.L204= | Silent (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- SRGAP1 | c.1062G>A p.E354= | Silent (SNP) | VAF 42/140 reads (30%) | called by muse, mutect2, varscan2
- ADGRG1 | c.*68C>T | 3'UTR (SNP) | VAF 32/60 reads (53%) | catalogued as rs919813529, COSV59651024; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AMPD2 | chr1:109620232 C>T | 5'Flank (SNP) | VAF 53/157 reads (34%) | called by muse, mutect2, varscan2
- AMPD2 | c.*321G>A | 3'UTR (SNP) | VAF 42/133 reads (32%) | called by muse, mutect2, varscan2
- ASXL2 | c.-174A>C | 5'UTR (SNP) | VAF 37/93 reads (40%) | called by muse, mutect2, varscan2
- CALN1 | c.*7685G>T | 3'UTR (SNP) | VAF 62/161 reads (39%) | called by muse, mutect2, varscan2
- CEP170 | c.1843+302T>A | Intron (SNP) | VAF 4/34 reads (12%) | catalogued as rs2789178; called by muse, mutect2
- CPD | c.*3516G>T | 3'UTR (SNP) | VAF 10/138 reads (7%) | called by muse, mutect2
- CPLX4 | c.*900del | 3'UTR (DEL) | VAF 12/33 reads (36%) | catalogued as rs959471921; called by mutect2, varscan2
- CYP11B1 | c.*401G>A | 3'UTR (SNP) | VAF 106/240 reads (44%) | catalogued as rs931233583; called by muse, mutect2, varscan2
- DDX60L | c.*934T>A | 3'UTR (SNP) | VAF 39/112 reads (35%) | called by muse, mutect2, varscan2
- DIPK2A | c.-328C>T | 5'UTR (SNP) | VAF 46/143 reads (32%) | called by muse, mutect2, varscan2
- DRD2 | c.*86G>A | 3'UTR (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- EIF2AK1 | c.*704C>A | 3'UTR (SNP) | VAF 169/444 reads (38%) | called by muse, mutect2, varscan2
- EIF3L | c.34-54C>G | Intron (SNP) | VAF 127/382 reads (33%) | called by muse, mutect2, varscan2
- EIF5AL1 | c.*452C>T | 3'UTR (SNP) | VAF 30/70 reads (43%) | catalogued as rs554011621; called by muse, mutect2, varscan2
- ERCC6L2 | c.-99G>A | 5'UTR (SNP) | VAF 27/83 reads (33%) | catalogued as rs1024183803; called by muse, mutect2, varscan2
- ERRFI1 | c.-1A>G | 5'UTR (SNP) | VAF 11/220 reads (5%) | called by muse, mutect2
- FAM133A | c.*273G>T | 3'UTR (SNP) | VAF 37/48 reads (77%) | called by muse, mutect2, varscan2
- FAM151A | c.-91G>A | 5'UTR (SNP) | VAF 39/111 reads (35%) | catalogued as COSV56363001; called by muse, mutect2, varscan2
- FCHO2 | c.*111dup | 3'UTR (INS) | VAF 62/218 reads (28%) | called by mutect2, pindel, varscan2
- FLVCR1 | c.*1179G>A | 3'UTR (SNP) | VAF 52/174 reads (30%) | called by muse, mutect2, varscan2
- GIMAP8 | c.*657G>T | 3'UTR (SNP) | VAF 49/190 reads (26%) | called by muse, mutect2, varscan2
- GPATCH11 | c.*490G>A | 3'UTR (SNP) | VAF 38/126 reads (30%) | catalogued as rs1418845751; called by muse, mutect2, varscan2
- GRM4 | c.520-9977G>A | Intron (SNP) | VAF 94/175 reads (54%) | catalogued as rs1288613855; called by muse, mutect2, varscan2
- GUCY1A1 | c.*1354G>T | 3'UTR (SNP) | VAF 20/68 reads (29%) | called by muse, mutect2, varscan2
- HDX | c.*3198G>C | 3'UTR (SNP) | VAF 40/52 reads (77%) | called by muse, mutect2, varscan2
- HOXA2 | c.392-319G>A | Intron (SNP) | VAF 55/194 reads (28%) | called by muse, mutect2, varscan2
- IGLL5 | c.-146G>A | 5'UTR (SNP) | VAF 56/86 reads (65%) | catalogued as rs1432501105; called by muse, varscan2
- IGLL5 | c.-76A>G | 5'UTR (SNP) | VAF 41/61 reads (67%) | called by muse, varscan2
- IL36B | c.261+1329T>G | Intron (SNP) | VAF 230/671 reads (34%) | called by muse, mutect2, varscan2
- JAM2 | c.*153del | 3'UTR (DEL) | VAF 52/139 reads (37%) | called by mutect2, pindel, varscan2
- JAZF1-AS1 | n.1132C>T | RNA (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- KCNH8 | c.812-69G>T | Intron (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- KCNV1 | chr8:109966622 C>T | 3'Flank (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- KMT5B | c.*1533A>T | 3'UTR (SNP) | VAF 55/136 reads (40%) | called by muse, mutect2, varscan2
- KPNA2P3 | n.479C>T | RNA (SNP) | VAF 120/360 reads (33%) | catalogued as rs114080170; called by muse, mutect2, varscan2
- KRTAP9-7 | c.*411A>T | 3'UTR (SNP) | VAF 7/95 reads (7%) | called by muse, mutect2
- LCP2 | c.*558G>A | 3'UTR (SNP) | VAF 58/150 reads (39%) | catalogued as rs59717613; called by muse, mutect2
- LRRTM4 | c.1551+314T>A | Intron (SNP) | VAF 28/92 reads (30%) | called by muse, mutect2, varscan2
- LTB | c.163-76T>G | Intron (SNP) | VAF 248/508 reads (49%) | called by muse, varscan2
- LTB | c.163-77C>G | Intron (SNP) | VAF 250/508 reads (49%) | catalogued as rs576331800, COSV53002587; called by muse, varscan2
- MMP8 | c.103-365del | Intron (DEL) | VAF 23/72 reads (32%) | called by mutect2, pindel, varscan2
- MTMR6 | c.*1805T>C | 3'UTR (SNP) | VAF 58/88 reads (66%) | called by muse, mutect2, varscan2
- NAA40 | c.*337C>A | 3'UTR (SNP) | VAF 13/201 reads (6%) | called by muse, mutect2
- NAMPTP1 | n.1247C>T | RNA (SNP) | VAF 82/224 reads (37%) | catalogued as rs201546401; called by muse, mutect2, varscan2
- NCL | c.*957A>G | 3'UTR (SNP) | VAF 12/42 reads (29%) | catalogued as rs188191647; called by muse, mutect2, varscan2
- NEGR1 | c.*1933A>G | 3'UTR (SNP) | VAF 22/58 reads (38%) | called by muse, mutect2, varscan2
- NFATC4 | c.101-36C>T | Intron (SNP) | VAF 209/493 reads (42%) | called by muse, mutect2, varscan2
- NOX5 | c.*3286G>A | 3'UTR (SNP) | VAF 63/228 reads (28%) | called by muse, mutect2, varscan2
- OBSCN | c.18662-2805A>T | Intron (SNP) | VAF 29/119 reads (24%) | called by muse, mutect2, varscan2
- OR52N4 | chr11:5755777 del A | 3'Flank (DEL) | VAF 34/120 reads (28%) | called by mutect2, pindel, varscan2
- PBX1 | c.*3916C>G | 3'UTR (SNP) | VAF 26/109 reads (24%) | called by muse, mutect2, varscan2
- PBX3 | c.201-143G>C | Intron (SNP) | VAF 66/119 reads (55%) | called by muse, mutect2
- PDXDC1 | c.-141del | 5'UTR (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel
- PPP1R12B | c.*2479A>G | 3'UTR (SNP) | VAF 22/143 reads (15%) | called by muse, mutect2, varscan2
- PRDM1 | c.*1522A>G | 3'UTR (SNP) | VAF 23/29 reads (79%) | called by muse, mutect2, varscan2
- PRXL2B | c.*420G>A | 3'UTR (SNP) | VAF 52/136 reads (38%) | called by muse, mutect2, varscan2
- S1PR3 | c.-147-169C>A | Intron (SNP) | VAF 61/177 reads (34%) | called by muse, mutect2, varscan2
- SLC38A7 | c.*31G>A | 3'UTR (SNP) | VAF 41/179 reads (23%) | called by muse, mutect2, varscan2
- SLC6A5 | c.*2557A>G | 3'UTR (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- SLC6A5 | c.*2558G>A | 3'UTR (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- SLF1 | c.1828-67A>G | Intron (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2
- SNF8 | c.-65G>C | 5'UTR (SNP) | VAF 19/59 reads (32%) | called by muse, mutect2, varscan2
- SPATA21 | c.34+3470C>T | Intron (SNP) | VAF 37/102 reads (36%) | catalogued as rs1243598370; called by muse, mutect2, varscan2
- ST8SIA2 | chr15:92472135 T>C | 3'Flank (SNP) | VAF 46/89 reads (52%) | called by muse, mutect2, varscan2
- TECR | c.118+150C>T | Intron (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2, varscan2
- TLN2 | c.*1583A>G | 3'UTR (SNP) | VAF 82/165 reads (50%) | called by muse, mutect2, varscan2
- TMEM87A | c.144+358G>A | Intron (SNP) | VAF 56/135 reads (41%) | catalogued as rs1358826099; called by muse, mutect2, varscan2
- TMPRSS13 | c.1282+876C>A | Intron (SNP) | VAF 20/338 reads (6%) | called by muse, mutect2
- TP63 | c.325-18593G>T | Intron (SNP) | VAF 41/106 reads (39%) | called by muse, mutect2, varscan2
- TRPA1 | c.-108T>A | 5'UTR (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- TRPS1 | chr8:115411608 T>C | 3'Flank (SNP) | VAF 43/100 reads (43%) | called by muse, mutect2, varscan2
- TSC22D2 | c.-475G>A | 5'UTR (SNP) | VAF 17/31 reads (55%) | called by muse, mutect2, varscan2
- TTC6 | chr14:37792321 C>G | 5'Flank (SNP) | VAF 52/221 reads (24%) | called by muse, mutect2, varscan2
- UBASH3B | c.*3918C>T | 3'UTR (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- UBXN7 | c.*7765C>T | 3'UTR (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- WAPL | c.*88T>C | 3'UTR (SNP) | VAF 12/246 reads (5%) | called by muse, mutect2
- WASHC4 | c.*1682G>T | 3'UTR (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- XIST | n.7553C>A | RNA (SNP) | VAF 58/75 reads (77%) | catalogued as rs1455776694; called by muse, mutect2, varscan2
- Z82198.2 | chr22:33166803 A>T | 3'Flank (SNP) | VAF 136/367 reads (37%) | called by muse, mutect2, varscan2
- ZIC4 | c.688+2044C>A | Intron (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- ZNF681 | c.*401A>T | 3'UTR (SNP) | VAF 53/131 reads (40%) | called by muse, mutect2, varscan2
